Surgical pathology report (de-identified scan), TCGA case TCGA-GR-A4D6, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site University of Nebraska Medical Center (UNMC), specimen TCGA-GR-A4D6-01A (Primary Tumor).

[page 1 of 4]
Department of Pathology and Microbiology

Name: [REDACTED]
Hosp N: [REDACTED] Acct No: [REDACTED]
DOB: [REDACTED] Age: [REDACTED]
Sex: F
Loc: [REDACTED] Room: [REDACTED]

Accession No:
Date Taken:
Date Received:
Submitted by:
Client:

Surgical Pathology

Final Diagnosis:

RIGHT NECK MASS, EXCISION: LYMPH NODE WITH DIFFUSE LARGE B-CELL LYMPHOMA, NONCLEAVED (SEE COMMENT). (B-DLCL-NC)

Diagnosis Comment:

The tumor cells have a germinal center B-cell phenotype.

ICD-O-3
lymphoma, diffuse,
large B-cell, NOS
9680/3 Signed:
Site: lymph node, cervical
9-20-12 RD C71.0

History:

The patient is a [REDACTED] year-old female with a right neck mass.

Intraoperative Diagnosis:

Neck, right, excisional biopsy: "Diagnostic tissue favor lymphoma." This is diagnosed by Dr. [REDACTED] and reported to Dr. [REDACTED] person.

Source/Gross:

The specimen is received fresh in a single container labeled [REDACTED] designated "right neck mass", and consists of a red-white soft tissue (2.7 x 2.5 x 1.1 cm). The specimen is bisected to reveal white-tan soft tissue. A representative section of this tissue is submitted for frozen section diagnosis (FSA1) and kept frozen in OCT for the Lymphoma Study Group protocol. The remainder of the specimen is serially sectioned to reveal fleshy white-tan soft tissue. The specimen is entirely submitted as per the Lymphoma Study Group protocol.

These materials were examined by all those listed to establish the diagnosis with the signature below the responsible staff pathologist

[page 2 of 4]
Name: [REDACTED] D.O.B. [REDACTED] Sex: F Accession No: [REDACTED]
Submitted [REDACTED] Date Taken [REDACTED] Hosp No: [REDACTED]

Surgical Pathology

Touch preps made - 3 made

Fixed in formalin for 24 hours - cassette A3 (1 piece, 2.3 x 1.1 x 0.2 cm)

cassette A4 (1 piece, 2.3 x 1.6 x 0.2 cm)

cassette A5 (1 piece, 2.0 x 2.4 x 0.2 cm)

cassette A6 (1 piece, 2.4 x 1.1 x 0.2 cm)

Frozen in foil for molecular diagnostic studies - 1 piece (1.1 x 0.7 x 0.3 cm)

Placed sterilely in media for cytogenetics - 1 piece (0.6 x 0.4 x 0.2 cm)

Fixed in B-plus - cassette A2 (3 pieces, 1.5 x 0.6 x 0.2 cm, 1.3 x 0.6 x 0.2 cm, and 0.6 x 0.5 x 0.3 cm)

Placed in cytogenetic media for molecular research hematology - 1 piece (0.7 x 0.4 x 0.2 cm)

Frozen in OCT for immunohistochemical studies - 1 piece (from frozen section A1) (2.0 x 1.2 x 0.3 cm)

Gross dictated by: [REDACTED]

Microscopic:

IMMUNOPEROXIDASE REPORT

PARAFFIN TISSUE - Done at [REDACTED]

B-Cell Markers

T-Cell Markers

Other Markers

CD20(L26)	+	CD45RO(UCHL1)	ND	CD45(LCA)	ND
CD79a	ND	CD43(L60)	ND	CD30(Ber-H2)	ND
CD10	+	CD3	-	CD15(Leu M1)	ND
		CD5	-	BCL-2	+
				BCL-6	+
				MUM1	+

INTERPRETATION: The paraffin markers indicate a B-cell phenotype.

Participating Resident: [REDACTED]

[page 3 of 4]
SURGICAL PATHOLOGY
SPECIMEN REQUEST FORM

PATIENT INFORMATION

NAME: [REDACTED]

MEDICAL

DATE OF

SEX: ☐ Male

MI

(AFFIX PATIENT LABEL HERE IF AVAILABLE)

CLINICAL HISTORY, PRE OPERATIVE DIAGNOSIS, POST OPERATIVE DIAGNOSIS, OR OTHER PERTINENT LABORATORY FINDINGS:

Right Neck Mass

SPECIAL REQUEST: (Please specify)

ORDERING PROVIDER: [REDACTED]

REFERRING PHYSICIAN: [REDACTED]

DATE/TIME SPECIMEN COLLECTION: [REDACTED]

SPECIMEN SOURCE:

① Right neck mass - [REDACTED]

FROZEN SECTION:

YES ☒NO ☐

OR NO. [REDACTED]

EXT. [REDACTED]

FROZEN SECTION DIAGNOSIS:

Diagnostic tissue favor
lymphoma

PATHOLOGIST SIGNATURE [REDACTED]

REPORT TO: [REDACTED]

TIME RECEIVED: [REDACTED]

TIME REPORTED: [REDACTED]

USE ONLY

CREW CHECKLIST

- ☒ Patient's ID Check
- ☒ Site Verification
- ☒ Label Verification
- ☒ Form Complete
- ☒ Specimen and Form Received

Nursing signature [REDACTED]

NOT TO BE FILED IN PERMANENT MEDICAL RECORD
SURGICAL PATHOLOGY SPECIMEN REQUEST FORM

[page 4 of 4]
IMMUNOPEROXIDASE REPORT

Patient: [REDACTED]

Surgical #: [REDACTED]

LR# [REDACTED]

Outside Surgical #: [REDACTED]

Date: [REDACTED]

☐ Referral Immunostains Reviewed AND/OR ☒ Done at [REDACTED]

PARAFFIN TISSUE - Outside Surgical # [REDACTED]

B-Cell Markers

T-Cell Markers

Other Markers

CD20(L26)	+	CD45RO(UCHL1)	—	CD45(LCA)	—
CD79a	—	CD43(L60)	—	CD30(Ber-H2)	—
Kappa (ISH)	—	CD3	—	CD15(Leu M1)	—
Lambda (ISH)	—	CD5	—	BCL-2	+
CD22	—	CD2	—	BCL-6	+
CD10	+	CD4	—	Cyclin D1	—
	—	CD7	—	ALK	—
	—	CD8	—	EMA	—
	—		—	Ki-67	—
	—		—	CD21	—
	—		—	EBERs	—
	—		—	MUM1	+
	—		—		—
	—		—		—
	—		—		—
	—		—		—
	—		—		—
	—		—		—
	—		—		—
	—		—		—

[- Indeterminate

If in situ hybridization, please check as appropriate:

ASR: ☐ Kappa/Lambda☐ EBV☐ Kappa/Lambda and EBV

Quick Test: ASRKL

ASREBV

ASRKLEBV

INTERPRETATION (Circle):

1. Monoclonal B-cell lymphoma (IgG, IgA, IgM, IgD, kappa, lambda).
2. B-cell lymphoma, surface Ig negative.
3. Consistent with peripheral T-cell lymphoma, (helper/inducer, cytotoxic/suppressor) cell type.
4. Consistent with Hodgkin's disease, (classical type, lymphocyte-predominant type).
5. The paraffin markers indicate a (B-cell) T-cell ; null) phenotype.
6. Specify: [REDACTED]

PATHOLOGIST: [REDACTED]

HIVAA Discrepancy		X
Reviewed: [REDACTED]	Date Reviewed: 9/19/12	

Source: NCI Genomic Data Commons file ea8762a6-09d3-4fea-88f7-342a9d3886c8 (TCGA-GR-A4D6.ABBC803D-EFC5-4223-8309-0F06F6AAAF9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).